Surgical pathology report (de-identified scan), TCGA case TCGA-BR-7704, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Asterand, specimen TCGA-BR-7704-01A (Primary Tumor).

[page 1 of 2]
Case ID	Gross Description	Microscopic Description	Diagnosis Details	Comments	Formatted Path Report
					STOMACH TISSUE CHECKLIST Specimen type: Gastrectomy Tumor site: Fundus Tumor size: 6 x 4 x 1.5 cm Tumor features: Exophytic (polypoid) Histologic type: Adenocarcinoma, intestinal type Histologic grade: Poorly differentiated Tumor extent: Serosa (visceral peritoneum) Lymph nodes: 0/3 positive for metastasis (Regional 0/3) Lymphatic invasion: Not specified Venous invasion: Not specified Perineural invasion: Not specified Margins: Not specified Evidence of neo-adjuvant treatment: Not specified Additional pathologic findings: Not specified Comments: None

[page 2 of 2]
ID	Laterality	Date of procurement
	Fundus	

Source: NCI Genomic Data Commons file 09e13f73-662d-48f3-82e8-61d967c5eb1e (TCGA-BR-7704.3A0B7E10-2BD2-48AA-937E-AA9706D14A38.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).